Somatic mutation profile of tumor specimen MP2PRT-PAPBSS-TMP1-A (aliquot MP2PRT-PAPBSS-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPBSS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.0 years (2,940 days).
Specimen MP2PRT-PAPBSS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d5187508-4a50-4d56-8e8a-068d618af34f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBSS-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBSS-NM1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0468890a-ec76-4e8b-bf3c-49200e0d5090

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Splice Site 1, Frame Shift Ins 1, RNA 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SETD2 | c.4715+1_4715+2insGTTAC p.X1572_splice | Splice Site (INS) | VAF 100/261 reads (38%) | hotspot (GDC flag); called by mutect2, pindel*, varscan2*
- PTGIS | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 235/479 reads (49%) | SIFT tolerated (0.53); PolyPhen benign (0.141); catalogued as rs780217825, COSV54834834; called by muse, mutect2, varscan2
- RANBP9 | c.1939dup p.M647Nfs*24 | Frame Shift Ins (INS) | VAF 80/193 reads (41%) | catalogued as rs751504188; called by mutect2, varscan2
- HELLPAR | n.199324G>A | RNA (SNP) | VAF 131/259 reads (51%) | catalogued as rs1343623338; called by muse, mutect2, varscan2
